Surgical pathology report (de-identified scan), TCGA case TCGA-DE-A4MB, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of North Carolina, specimen TCGA-DE-A4MB-01A (Primary Tumor).

[page 1 of 5]
ICD-0 3

CACF - carcinoma, papillary, thyroid 8260/3
Path: Carcinoma, papillary and follicular 8340/3
Site: thyroid. NOS C73.9

SURGICAL PATHOLOGY

W/ 8/2/12

Case Number :

Diagnosis:

A: Thyroid cartilage, left margin, biopsy

- Positive for invasive carcinoma, consistent with papillary thyroid carcinoma.

B: Lymph nodes, level 5, left neck, regional node dissection

- No tumor seen in five lymph nodes (0/5).

- Benign skeletal muscle and soft tissue.

C: Lymph nodes, level 4, left neck, regional node dissection

- No tumor seen in nine lymph nodes (0/9).

- Benign skeletal muscle and soft tissue.

D: Lymph nodes, level 3, left neck, regional node dissection

- Metastatic papillary thyroid carcinoma in 1 of 13 lymph nodes (1/13); maximum size of metastasis <0.1 cm; negative for extracapsular extension.

E: Lymph nodes, level 2, left neck, regional node dissection

- Metastatic papillary thyroid carcinoma in 2 of 9 lymph nodes (2/9); maximum size of metastasis 0.7 cm; negative for extracapsular extension.

F: Thyroid, total thyroidectomy

Tumor histologic type: papillary thyroid carcinoma, papillary and follicular variants

Tumor size: 4.4 cm maximum tumor size

Tumor growth pattern: infiltrative

Tumor focality: multifocal; single dominant mass within left lobe with multiple papillary microcarcinomas identified in right lobe, measuring 0.1 cm, 0.1 cm, 0.2 cm and <0.1 cm (F2)

Extent of invasion:

Capsular Invasion: not applicable

Lymphovascular: not identified

Blood vascular: not identified

Extra thyroidal extension: extensive invasion into perithyroidal soft tissues with invasion of skeletal muscle identified

[page 2 of 5]
Surgical margins: Carcinoma extensively involves the posterior resection margin (F5, F6, F7, F8, F9, F10, F11); carcinoma involves the inferior en face margin (F12); carcinoma is very close <0.1 cm from the anterior resection margin (F5, F8, F9, F10).

Status of thyroid gland away from tumor: multinodular thyroid

Lymph nodes: separately submitted; total lymph node count for all specimens is 3 of 36 lymph nodes involved by metastatic papillary thyroid carcinoma (3/36)

Size of largest metastasis (greatest dimension): 0.7 cm

Extracapsular (perinodal) extension: not identified

Other significant findings: benign thyroid tissue

AJCC PATHOLOGIC TNM STAGE: pT3 pN1b

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Comment:

The frozen section diagnosis is confirmed.

Intraoperative Consult Diagnosis:

A frozen section was requested by

FSA1: Thyroid cartilage margin, left, biopsy

- Positive for carcinoma

Dr. concurs.

Frozen Section Pathologist: , MD

Clinical History:

-year-old female with left thyroid mass. FNA was strongly suspicious for malignancy papillary vs. possible medullary.

Gross Description:

Specimen A is labeled "left thyroid cartilage margin" and is a 6 x 5 x 3 mm aggregate of firm red/yellow tissue, FSA1,

[page 3 of 5]
Specimen B is labeled "left neck level 5" and is a 3.6 x 2.5 x 1.5 cm aggregate of fibrofatty tissue and muscle. The specimen is dissected for lymph node candidates. Four lymph node candidates measuring up to 0.4 cm in greatest dimension are identified.

Block Summary:

- B1 - Four lymph node candidates
- B2 - Sample from muscle

Specimen C is labeled "left neck level 4" and is a 3.4 x 3.2 x 1.0 cm aggregate of yellow/tan fibrofatty tissue and attached muscle, dissected for lymph node candidates. Lymph node candidates measuring up to 0.6 cm in greatest dimension are identified.

Block Summary:

- C1 - One lymph node candidate, bisected
- C2 - Five lymph node candidates
- C3 - Four lymph node candidates
- C4 - Representative section from skeletal muscle

Specimen D is labeled "left neck level 3" and is a 4.3 x 2.5 x 1.0 cm aggregate of yellow/tan fibrofatty tissue, dissected for lymph node candidates. Lymph node candidates measuring up to 1.2 cm in greatest dimension are identified.

Block Summary:

- D1 - Four lymph node candidates
- D2 - Three lymph node candidates
- D3 - One lymph node candidate

Specimen E is labeled "left neck level 2" and is a 3.7 x 2.4 x 1.0 cm aggregate of focally cauterized yellow/tan fibrofatty tissue, dissected for lymph node candidates. Lymph node candidates measuring up to 1.4 cm in greatest dimension are identified.

Block Summary:

- E1 - Three lymph node candidates
- E2 - Two lymph node candidates
- E3 - One lymph node candidate
- E4 - One lymph node candidate, bisected

Specimen F:

Specimen fixation: Formalin

[page 4 of 5]
Type of specimen: Total thyroidectomy

Size and weight of specimen: 30.5 grams, 7.9 x 5.0 x 3.0 cm overall. Composed of a 5.6 x 4.8 x 1.8 cm left lobe, 3.4 x 2.3 x 1.1 cm right lobe

Orientation: Inking: anterior/blue, posterior/black, and isthmus/yellow

Tumor location: The tumor involves the entire left thyroid lobe. The isthmus and right lobe are uninvolved.

Focality: Unifocal

Dominant tumor: Left thyroid lobe

Tumor description: Solid, firm, ill-defined tan and gritty

Tumor size: 4.4 x 3.7 x 1.8 cm

Confinement/non-confinement : Appears to extend beyond the thyroid gland on the left hand side posteriorly and inferiorly and possibly superiorly.

Distance of tumor to surgical margins: The tumor abuts the blue-inked anterior margin, the black inked posterior margin along the majority of the surface.

Appearance of thyroid gland away from tumor: The right lobe of the thyroid is dark red and homogeneous with no nodules or masses appreciated. The isthmus is grossly unremarkable. There is a 1.2 cm in diameter colloid nodule located along the anterior medial edge of the tumor near the isthmus.

Parathyroids: Not identified

Tissue submitted for special investigations: Tumor is given to tissue procurement.

Lymph nodes: Submitted separately.

Digital photograph taken: No

Block Summary:

[page 5 of 5]
Inking: anterior/blue, posterior/black and isthmus/yellow
F1-F2 - Representative sections from right lobe
F3 - Perpendicular sections of left thyroid lobe, superior margin
F4-F5 - Section from superior portion of nodule
F6-F7 - Representative section of mass with colloid nodule towards isthmus (medial)
F8 - Central portion of tumor along lateral edge
F9 - Central portion of tumor showing relationship to posterior and anterior margins
F10 - Inferior edge of tumor towards lateral edge
F11 - Inferior edge of tissue inferior edge of mass in soft tissue
F12 - En face inferior margin
F13 - Fat attached to inferior pole of mass

Discrepancy		☒
Procedure Site Discrepancy		☒
History Discrepancy		☒
Procedure History		☒
Discrepancy Primary Node		☒
Case		
Reviewed		

Source: NCI Genomic Data Commons file 7bbe0662-2c93-4594-92be-5d9b79f01adf (TCGA-DE-A4MB.395EF461-5733-4651-800E-7831D1ACD609.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).